FM case AD12131 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Gallbladder.
https://portal.gdc.cancer.gov/cases/77349c4b-8425-4c0e-a8b2-644332b08e93

Female, 51.6 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the gallbladder; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
